Somatic mutation profile of tumor specimen TCGA-55-1594-01A (aliquot TCGA-55-1594-01A-01W-0928-08) from TCGA case TCGA-55-1594, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-55-1594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3e3092e-9d8a-4ee0-aca9-b96d4ae85ff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1594-11A (Solid Tissue Normal), aliquot TCGA-55-1594-11A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d54ec8e2-d534-4034-a036-d94c67cfd424

The open-access MAF lists 164 somatic variants for this specimen: 124 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 37, Nonsense Mutation 7, Frame Shift Ins 6, Frame Shift Del 2, Splice Site 2, 3'Flank 1, 3'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 85/179 reads (47%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52211567; called by muse, mutect2, varscan2
- ADARB1 | c.2054C>T p.S685F (on ENST00000360697 / NM_001346687.2; = p.S645F on NM_001112.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV62348008; called by muse, mutect2, varscan2
- AGAP4 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1347036003; called by mutect2, varscan2
- ATMIN | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55147562; called by muse, mutect2, varscan2
- C9orf131 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV56614041; called by muse, mutect2, varscan2
- CAPN3 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as COSV55521867; called by muse, varscan2
- CCDC158 | c.3044C>G p.S1015C | Missense Mutation (SNP) | VAF 131/694 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66357157; called by muse, mutect2, varscan2
- CCDC39 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56493284; called by muse, mutect2, varscan2
- CCT8L2 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.308); catalogued as COSV63463644, COSV63463760; called by muse, mutect2, varscan2
- CDH9 | c.1922A>G p.K641R | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV50433532; called by muse, varscan2
- CDKN2A | c.300_301insT p.G101Wfs*19 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as COSV58697242; called by mutect2, varscan2
- CDKN2A | c.298dup p.A100Gfs*20 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | catalogued as CI119690; called by mutect2*, pindel, varscan2*
- CEP152 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 102/303 reads (34%) | catalogued as rs945108502, COSV57864597; called by muse, mutect2, varscan2
- CEP57 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57690358; called by muse, mutect2, varscan2
- CLCA4 | c.2322G>C p.W774C | Missense Mutation (SNP) | VAF 311/726 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218044991, COSV65285115; called by muse, mutect2, varscan2
- CLK1 | c.1141-1G>T p.X381_splice | Splice Site (SNP) | VAF 46/278 reads (17%) | catalogued as COSV58433599; called by muse, mutect2, varscan2
- CMYA5 | c.11164A>G p.T3722A | Missense Mutation (SNP) | VAF 128/279 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV71409343; called by muse, mutect2, varscan2
- CNMD | c.71dup p.A25Gfs*78 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs768157613; called by pindel, varscan2
- COL11A1 | c.4225C>T p.L1409F | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1435827751, COSV62178944, COSV62196590; called by muse, varscan2
- CRACD | c.1963dup p.R655Pfs*28 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs769175297; called by pindel, varscan2
- CSMD3 | c.10322G>A p.G3441D (on ENST00000297405 / NM_001363185.1; = p.G3272D on NM_052900.3) | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52310887; called by muse, mutect2
- DCAF1 | c.4443G>T p.E1481D | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); catalogued as COSV60046466; called by muse, mutect2, varscan2
- DCST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs769529661, COSV55063085; called by muse, mutect2, varscan2
- DDX42 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV63791344; called by muse, mutect2, varscan2
- DIDO1 | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56632470; called by muse, mutect2, varscan2
- DNAI2 | c.799T>G p.Y267D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV56762346; called by muse, mutect2, varscan2
- EBF3 | c.1072C>T p.Q358* (on ENST00000355311 / NM_001375392.1; = p.Q349* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/133 reads (17%) | catalogued as COSV62478994; called by muse, mutect2, varscan2
- EGFLAM | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs267600618, COSV59316379; called by muse, mutect2, varscan2
- EMSY | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 108/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1015568567, COSV58265540; called by muse, mutect2, varscan2
- EXPH5 | c.5773G>A p.D1925N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV56207960; called by muse, mutect2, varscan2
- FAM184A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58858621; called by muse, mutect2, varscan2
- FAM47B | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 87/129 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs778028004, COSV61453478; called by muse, mutect2, varscan2
- FBN2 | c.8140G>T p.E2714* | Nonsense Mutation (SNP) | VAF 173/326 reads (53%) | catalogued as COSV52544134; called by muse, mutect2, varscan2
- FGF9 | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as COSV66645707; called by muse, mutect2, varscan2
- FMO3 | c.1062A>C p.K354N | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63008522; called by muse, mutect2, varscan2
- FSHR | c.433del p.Q145Kfs*11 | Frame Shift Del (DEL) | VAF 69/497 reads (14%) | catalogued as COSV100436354; called by mutect2, pindel, varscan2
- FYB2 | c.1201del p.E401Nfs*10 | Frame Shift Del (DEL) | VAF 91/478 reads (19%) | catalogued as COSV58588452; called by mutect2, pindel, varscan2
- GADL1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs751396281, COSV56985424; called by muse, mutect2, varscan2
- GGN | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV53058889, COSV53059515; called by muse, mutect2, varscan2
- GOLGA1 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1396660217, COSV65230986; called by muse, mutect2, varscan2
- GOLM1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV57415999; called by muse, mutect2, varscan2
- GPR152 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56888052; called by muse, mutect2, varscan2
- HERC1 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71250117; called by muse, mutect2, varscan2
- HNRNPC | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); catalogued as COSV60146135; called by muse, mutect2
- HSDL2 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 112/471 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52717196; called by muse, mutect2, varscan2
- IFNL3 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69830193; called by muse, mutect2, varscan2
- INTS2 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV52156454; called by muse, mutect2, varscan2
- ITPR3 | c.1181C>A p.T394N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65412004; called by muse, mutect2, varscan2
- JADE3 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1556373000, COSV54470132; called by muse, mutect2, varscan2
- KCNH7 | c.2578G>C p.E860Q | Missense Mutation (SNP) | VAF 91/167 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59812819; called by muse, mutect2, varscan2
- KCNK18 | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57973169; called by muse, mutect2, varscan2
- KLHL25 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61996461; called by muse, mutect2
- KLK14 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50071089; called by muse, mutect2, varscan2
- KPRP | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100908697, COSV64222956; called by muse, mutect2, varscan2
- KRT74 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59773566; called by muse, mutect2, varscan2
- LATS2 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV66879628; called by muse, mutect2, varscan2
- LDHC | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55005949; called by mutect2, varscan2
- LGI1 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65059205; called by muse, mutect2, varscan2
- LHX8 | c.409T>G p.S137A | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53959989; called by muse, mutect2, varscan2
- LIPI | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60715928; called by muse, mutect2
- LUZP2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 96/491 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61218258; called by muse, varscan2
- MARCO | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59058404; called by muse, mutect2, varscan2
- MDGA2 | c.1139T>A p.I380N (on ENST00000399232 / NM_001113498.2; = p.I82N on NM_182830.4) | Missense Mutation (SNP) | VAF 190/3978 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV62114428; called by muse, mutect2
- MROH7 | c.3746G>A p.R1249K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV64888250; called by muse, mutect2, varscan2
- MS4A15 | c.668C>T p.A223V (on ENST00000405633 / NM_001098835.2; = p.A130V on NM_152717.3) | Missense Mutation (SNP) | VAF 144/504 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV61961830; called by muse, mutect2, varscan2
- MYCBP2 | c.829C>G p.Q277E (on ENST00000357337; = p.Q315E on NM_015057.5) | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV62038264; called by muse, mutect2, varscan2
- OCA2 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62357436; called by muse, mutect2, varscan2
- OCA2 | c.1549T>A p.C517S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV62357446; called by muse, mutect2, varscan2
- OR4C11 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs753199652, COSV56354938; called by muse, mutect2, varscan2
- OR51Q1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as COSV56180547; called by muse, mutect2, varscan2
- OR56A3 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 50/493 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61569997; called by muse, mutect2, varscan2
- PCDHB1 | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60633204; called by muse, mutect2, varscan2
- PCDHB7 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50813128; called by muse, mutect2, varscan2
- PCOLCE2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.796); catalogued as COSV56002004; called by muse, mutect2, varscan2
- PI15 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99478142; called by muse, mutect2, varscan2
- PIGG | c.1543G>C p.A515P (on ENST00000453061 / NM_001127178.3; = p.A507P on NM_017733.4) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV56321351; called by muse, mutect2, varscan2
- PIGM | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63636053; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 24/189 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3R3 | c.1138T>C p.F380L | Missense Mutation (SNP) | VAF 189/960 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53111057; called by muse, mutect2, varscan2
- PNPLA8 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV57554709; called by muse, mutect2
- POLR1A | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 97/622 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772030966, COSV55699465; called by muse, mutect2, varscan2
- RECK | c.1994A>T p.Q665L | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65036291; called by muse, mutect2, varscan2
- RIN3 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53652630; called by muse, mutect2, varscan2
- RMND5B | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1561637151, COSV57746099; called by mutect2, varscan2
- RPN2 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 197/701 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV52908850; called by muse, varscan2
- RYR2 | c.14841G>T p.R4947S | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1252294768, COSV63690632, COSV63712252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAP30BP | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53130224; called by muse, mutect2, varscan2
- SEZ6L | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50685246; called by muse, mutect2, varscan2
- SH2B1 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV59466717; called by muse, mutect2, varscan2
- SHPRH | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51617360; called by muse, mutect2
- SLC27A1 | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53100677; called by muse, mutect2, varscan2
- SLC32A1 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV54148324; called by muse, mutect2, varscan2
- SLC5A7 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50902901; called by muse, mutect2
- SLC6A16 | c.911T>G p.I304S | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60030298; called by muse, mutect2, varscan2
- SORCS1 | c.1892T>G p.F631C | Missense Mutation (SNP) | VAF 170/373 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53903433; called by muse, mutect2, varscan2
- SPDYC | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs372669084, COSV65865129; called by muse, mutect2, varscan2
- SRGAP1 | c.2533T>A p.L845I | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61903296; called by muse, mutect2, varscan2
- SRSF11 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63938356, COSV63939551; called by muse, mutect2, varscan2
- TANK | c.88T>A p.L30I | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV52047727; called by muse, mutect2, varscan2
- TEX33 | c.723T>A p.H241Q (on ENST00000381821 / NM_001163857.2; = p.H156Q on NM_178552.4) | Missense Mutation (SNP) | VAF 204/497 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67822920; called by muse, mutect2, varscan2
- TM4SF19 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56557608; called by muse, mutect2, varscan2
- TNN | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs367714075, COSV53434983; called by mutect2, varscan2
- TRPC3 | c.1858G>T p.V620L (on ENST00000379645 / NM_001366479.2; = p.V547L on NM_003305.2) | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53380965; called by muse, mutect2, varscan2
- TRPM3 | c.695A>G p.H232R (on ENST00000357533 / NM_001366142.2; = p.H77R on NM_020952.6) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV62474030; called by muse, mutect2
- TSPAN3 | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51216068; called by muse, mutect2, varscan2
- UNC13C | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1255994307, COSV52886584, COSV52913750; called by muse, mutect2, varscan2
- VCAN | c.2579G>A p.S860N | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs931658666, COSV54096285, COSV54105774; called by muse, mutect2
- VCP | c.1937C>A p.P646Q | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62722136; called by muse, mutect2, varscan2
- WDR70 | c.1754C>G p.S585C | Missense Mutation (SNP) | VAF 156/516 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54283317; called by muse, mutect2, varscan2
- ZMYM2 | c.2100G>C p.K700N | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs535395618, COSV67037454; called by muse, mutect2, varscan2
- ZNF141 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53661643; called by muse, mutect2, varscan2
- ZNF160 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV62000907, COSV62001388; called by muse, mutect2, varscan2
- ZNF283 | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61032956; called by muse, mutect2, varscan2
- ZNF566 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | catalogued as COSV67574730; called by muse, mutect2, varscan2
- ZNF611 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.454); catalogued as COSV60543263; called by muse, mutect2, varscan2
- ZNF638 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 100/688 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV52496581; called by muse, varscan2
- ZNF70 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 60/357 reads (17%) | catalogued as COSV59533799; called by muse, mutect2, varscan2
- ABCC1 | c.2290_2292del p.K764del | In Frame Del (DEL) | VAF 20/188 reads (11%) | called by mutect2, pindel
- AFF2 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 29/421 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CRYBG1 | c.2568G>T p.Q856H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- EIF5B | c.1840_1842+4del p.X614_splice | Splice Site (DEL) | VAF 40/403 reads (10%) | called by mutect2, pindel
- NRP1 | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.259); called by mutect2, varscan2
- TAS2R31 | c.28dup p.S10Ffs*15 | Frame Shift Ins (INS) | VAF 50/202 reads (25%) | called by mutect2, pindel, varscan2
- ACTRT3 | c.771C>T p.A257= | Silent (SNP) | VAF 10/33 reads (30%) | called by mutect2, varscan2
- AGPS | c.1875A>G p.Q625= | Silent (SNP) | VAF 42/297 reads (14%) | catalogued as COSV51568909; called by muse, mutect2, varscan2
- AOX1 | c.720A>G p.R240= | Silent (SNP) | VAF 111/598 reads (19%) | catalogued as rs908276524, COSV65983868; called by muse, mutect2, varscan2
- ATP6V1A | c.666A>C p.P222= | Silent (SNP) | VAF 98/669 reads (15%) | catalogued as COSV56364560; called by muse, mutect2, varscan2
- BAZ2A | c.2430G>A p.R810= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV51643388; called by muse, mutect2, varscan2
- CLSTN2 | c.201C>T p.A67= | Silent (SNP) | VAF 38/295 reads (13%) | catalogued as rs1294909541, COSV71724865; called by muse, mutect2, varscan2
- CTBP2 | c.648G>T p.G216= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV58337852; called by muse, mutect2, varscan2
- DGLUCY | c.1785G>T p.L595= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV56366072; called by muse, mutect2, varscan2
- FSIP2 | c.20118G>C p.T6706= | Silent (SNP) | VAF 63/129 reads (49%) | catalogued as rs779866454, COSV58090474, COSV58100545; called by muse, mutect2, varscan2
- GALNT11 | c.1773C>T p.V591= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs368113531; called by muse, mutect2, varscan2
- ID3 | c.156G>A p.R52= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV65801486; called by muse, mutect2, varscan2
- LIG3 | c.2616G>A p.K872= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as COSV99252911; called by muse, mutect2
- LZTS1 | c.156C>T p.H52= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as rs745621744, COSV56117136; called by muse, mutect2, varscan2
- MAN1A2 | c.366A>C p.A122= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV62981474; called by muse, mutect2, varscan2
- MORC1 | c.1131C>T p.I377= | Silent (SNP) | VAF 172/543 reads (32%) | catalogued as rs144305402, COSV51725258; called by muse, mutect2, varscan2
- MSH2 | c.2673G>C p.V891= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV51884709; called by mutect2, varscan2
- MYO7B | c.2796G>A p.Q932= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1156874045, COSV67351715; called by mutect2, varscan2
- NFASC | c.2046C>A p.P682= (on ENST00000339876 / NM_001378329.1; = p.P678= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as COSV58361844, COSV58379379; called by muse, mutect2, varscan2
- NFXL1 | c.1540A>C p.R514= | Silent (SNP) | VAF 57/196 reads (29%) | catalogued as COSV61200704; called by muse, mutect2, varscan2
- NSUN6 | c.171G>A p.V57= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as rs369325065; called by muse, mutect2, varscan2
- PARP11 | c.246C>T p.F82= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV57393794; called by muse, mutect2, varscan2
- PCDHB4 | c.1740G>A p.E580= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV52026763; called by mutect2, varscan2
- PI15 | c.324C>T p.C108= | Silent (SNP) | VAF 66/325 reads (20%) | catalogued as COSV52641257, COSV52641429; called by muse, mutect2, varscan2
- RPN2 | c.435C>G p.L145= | Silent (SNP) | VAF 155/615 reads (25%) | catalogued as COSV52908863; called by muse, varscan2
- SLC35A1 | c.624G>A p.V208= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1397802346, COSV65780717; called by muse, mutect2, varscan2
- SLC44A4 | c.1731G>A p.A577= | Silent (SNP) | VAF 28/203 reads (14%) | catalogued as rs142009471; called by muse, mutect2, varscan2
- SLCO4C1 | c.339C>T p.L113= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV60520050; called by muse, mutect2, varscan2
- SLITRK5 | c.1131G>T p.A377= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1261174372, COSV61524639; called by muse, mutect2, varscan2
- SPAM1 | c.1422G>A p.E474= | Silent (SNP) | VAF 68/243 reads (28%) | catalogued as COSV56147513; called by muse, mutect2, varscan2
- TNMD | c.630C>G p.A210= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as COSV65977774; called by muse, mutect2, varscan2
- TOMM70 | c.795G>T p.T265= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as rs778126106, COSV52522303, COSV52525557; called by muse, mutect2, varscan2
- TSSK3 | c.495G>C p.L165= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV61983355; called by muse, mutect2, varscan2
- USP47 | c.1179C>T p.F393= (on ENST00000399455 / NM_001372095.1; = p.F305= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as COSV100360024, COSV60467803; called by muse, mutect2
- VPS33A | c.126A>T p.L42= | Silent (SNP) | VAF 37/190 reads (19%) | catalogued as COSV57358792; called by muse, mutect2, varscan2
- VSTM1 | c.399C>T p.T133= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV58076773; called by muse, mutect2, varscan2
- ZNF208 | c.3504C>A p.P1168= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV68112241; called by muse, mutect2, varscan2
- ZNF655 | c.1335C>T p.F445= | Silent (SNP) | VAF 48/282 reads (17%) | catalogued as rs372713595, COSV53160155; called by muse, varscan2
- ALMS1P1 | chr2:73701157 ins C | 3'Flank (INS) | VAF 13/95 reads (14%) | catalogued as rs760920589; called by mutect2, varscan2
- CLVS1 | c.*2C>G | 3'UTR (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- ZNF160 | c.271+799T>G | Intron (SNP) | VAF 50/139 reads (36%) | catalogued as COSV100762417; called by muse, mutect2, varscan2
